Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A46F, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A46F-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -

NO EVIDENCE OF NEOPLASIA IN FOURTEEN (14) LYMPH NODES EXAMINED.

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -

METASTATIC ADENOCARCINOMA IN ONE (1) OF NINE (9) LYMPH NODES EXAMINED.

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE $4 + 4 = 8$ WITH TERTIARY GLEASON PATTERNS 3 AND 5.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.4 CM.
- C. THE CARCINOMA INVOLVES APPROXIMATELY 15% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS ESTABLISHED EXTRACAPSULAR EXTENSION.
- E. THE EXTRACAPSULAR EXTENSION IS SEEN IN THE POSTERIOR RIGHT BASE AND MID REGIONS (SLIDES 3AA-3DD).
- F. THE RIGHT SEMINAL VESICLE IS INVOLVED BY CARCINOMA.
- G. THE LEFT SEMINAL VESICLE WALL IS FREE OF CARCINOMA, BUT THERE IS TUMOR IN THE SOFT TISSUE SURROUNDING THE WALL.
- H. ALTHOUGH ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA, THE CARCINOMA IS VERY CLOSE (LESS THAN 0.1 CM) TO THE POSTERIOR RIGHT BASE REGION MARGIN (SLIDE 3DD).
- I. EXTENSIVE PERINEURAL INVASION IS IDENTIFIED.
- J. ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- K. EXTENSIVE HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- L. PATHOLOGIC TNM STAGE: pT3b N1 MX.
- M. TNM HISTOLOGIC GRADE = G4.
- N. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC MODERATELY ACTIVE PROSTATITIS ARE NOTED.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 9.1
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	8
GLEASON 4/5 PERCENTAGE:	80%
WEIGHT OF PROSTATE:	64.58gm
TUMOR SIZE:	Maximum dimension: 1.4 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - NOS
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	Yes
SEMINAL VESICLE INVASION:	Yes
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	23
LYMPH NODES POSITIVE:	1
T STAGE, PATHOLOGIC:	pT3b
N STAGE, PATHOLOGIC:	pN1
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

ICD-O-3

CQCF: Adenocarcinoma, acinar 8550/3

Path: adenocarcinoma, NOS 8140/3

Site: prostate, NOS C61.9

fw
8/26/12

TIPIAA Discrepancy	☒	☐

[page 2 of 2]
FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -

NO EVIDENCE OF NEOPLASIA IN FOURTEEN (14) LYMPH NODES EXAMINED.

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -

METASTATIC ADENOCARCINOMA IN ONE (1) OF NINE (9) LYMPH NODES EXAMINED.

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE $4 + 4 = 8$ WITH TERTIARY GLEASON PATTERNS 3 AND 5.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.4 CM.
- C. THE CARCINOMA INVOLVES APPROXIMATELY 15% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS ESTABLISHED EXTRACAPSULAR EXTENSION.
- E. THE EXTRACAPSULAR EXTENSION IS SEEN IN THE POSTERIOR RIGHT BASE AND MID REGIONS (SLIDES 3AA-3DD).
- F. THE RIGHT SEMINAL VESICLE IS INVOLVED BY CARCINOMA.
- G. THE LEFT SEMINAL VESICLE WALL IS FREE OF CARCINOMA, BUT THERE IS TUMOR IN THE SOFT TISSUE SURROUNDING THE WALL.
- H. ALTHOUGH ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA, THE CARCINOMA IS VERY CLOSE (LESS THAN 0.1 CM) TO THE POSTERIOR RIGHT BASE REGION MARGIN (SLIDE 3DD).
- I. EXTENSIVE PERINEURAL INVASION IS IDENTIFIED.
- J. ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- K. EXTENSIVE HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- L. PATHOLOGIC TNM STAGE: pT3b N1 MX.
- M. TNM HISTOLOGIC GRADE = G4.
- N. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC MODERATELY ACTIVE PROSTATITIS ARE NOTED.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 9.1
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	8
GLEASON 4/5 PERCENTAGE:	80%
WEIGHT OF PROSTATE:	64.56gm
TUMOR SIZE:	Maximum dimension: 1.4 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - NOS
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	Yes
SEMINAL VESICLE INVASION:	Yes
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	23
LYMPH NODES POSITIVE:	1
T STAGE, PATHOLOGIC:	pT3b
N STAGE, PATHOLOGIC:	pN1
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 8c62c373-f4b1-437a-bda5-bb1c74f2f58e (TCGA-EJ-A46F.E424A7C8-4DDD-4ECC-A0B4-DF22A9996D01.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).